Somatic mutation profile of tumor specimen ALCH-B1YH-TTP1-A (aliquot ALCH-B1YH-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1YH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,191 days).
Specimen ALCH-B1YH-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 385f6e17-e4a8-446b-8a44-0751a9f9584d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YH-NB1-A (Blood Derived Normal), aliquot ALCH-B1YH-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4d359ef-5e58-4697-8193-bbc804efa6aa

The open-access MAF lists 2,106 somatic variants for this specimen: 1,435 protein-altering or splice-affecting, 412 silent, 259 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,189, Silent 412, Nonsense Mutation 127, Intron 110, Splice Site 45, 3'UTR 45, Frame Shift Del 44, RNA 43, 5'Flank 22, 5'UTR 21, 3'Flank 18, Splice Region 16.

Variants (750 of 2,106; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.7277G>T p.R2426L | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373521030, COSV62100802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs869025531, CM1210056, COSV65109013, COSV65110174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 12/110 reads (11%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ABCA12 | c.7704C>G p.D2568E (on ENST00000272895 / NM_173076.3; = p.D2250E on NM_015657.3) | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55947672; called by muse, mutect2, varscan2
- ABCA12 | c.3795C>A p.F1265L (on ENST00000272895 / NM_173076.3; = p.F947L on NM_015657.3) | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as COSV55969992, COSV55970062; called by muse, mutect2, varscan2
- ABCA3 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs753505428; called by muse, varscan2
- ADAM2 | c.1525T>A p.S509T | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99697500; called by muse, mutect2
- ADAMTS14 | c.1551G>T p.K517N | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV64599550; called by muse, mutect2, varscan2
- ADCY5 | c.2036C>A p.P679H | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59203738; called by muse, mutect2, varscan2
- ADCY8 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53917003; called by muse, mutect2, varscan2
- ADGRB3 | c.869-1G>T p.X290_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as COSV65407411; called by muse, mutect2, varscan2
- ADGRB3 | c.1229G>T p.S410I | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65411592; called by muse, mutect2, varscan2
- ADGRF4 | c.467C>A p.T156K | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV51953208; called by muse, varscan2
- ADGRG4 | c.2000C>G p.S667C | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54959077; called by muse, mutect2, varscan2
- ADSS2 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as COSV100836779, COSV63694837; called by muse, mutect2, varscan2
- AFP | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV56925191; called by muse, mutect2, varscan2
- AK9 | c.5006G>T p.R1669M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101413981; called by muse, mutect2, varscan2
- ALCAM | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.125); catalogued as rs781270007; called by muse, mutect2, varscan2
- AMER3 | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs763893750, COSV58469968; called by muse, mutect2, varscan2
- ANAPC1 | c.5315C>G p.S1772C | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV100594817; called by muse, mutect2, varscan2
- ANAPC2 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs147941604; called by muse, mutect2, varscan2
- ANKAR | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs779093435; called by muse, mutect2, varscan2
- ANKRD34A | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV60160643; called by muse, mutect2, varscan2
- ANKRD36C | c.2395G>T p.D799Y | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV99753900; called by muse, mutect2, varscan2
- ANO3 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104375639; called by muse, mutect2, varscan2
- AP002008.2 | n.1952G>T | Splice Region (SNP) | VAF 20/62 reads (32%) | catalogued as rs1452420167; called by muse, mutect2, varscan2
- AP3D1 | c.3261G>C p.K1087N | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); catalogued as COSV61426373; called by muse, mutect2, varscan2
- APC | c.4037C>G p.S1346* | Nonsense Mutation (SNP) | VAF 55/110 reads (50%) | catalogued as COSV57325995, COSV57328373, COSV57364395; called by muse, mutect2, varscan2
- APC2 | c.5030G>A p.R1677Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as rs541275280; called by muse, mutect2, varscan2
- APH1A | c.32T>C p.F11S | Missense Mutation (SNP) | VAF 96/198 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs782078785, COSV52528464; called by muse, mutect2, varscan2
- APOB | c.5990A>G p.D1997G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.401); catalogued as rs752203499; called by muse, mutect2, varscan2
- APOBR | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.675); catalogued as rs1007959008; called by muse, mutect2
- ARHGAP20 | c.630+1G>A p.X210_splice | Splice Site (SNP) | VAF 30/96 reads (31%) | catalogued as rs1449319024, COSV52814832; called by muse, mutect2, varscan2
- ARHGAP35 | c.2749G>T p.G917* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as COSV68335933; called by muse, mutect2, varscan2
- ASPM | c.5294G>T p.R1765I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99660817; called by muse, mutect2, varscan2
- ATL3 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs752401432; called by muse, varscan2
- ATP13A4 | c.3436C>G p.Q1146E | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100710862, COSV61325570; called by muse, mutect2, varscan2
- ATP8B4 | c.2354T>A p.V785E | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52717645; called by muse, mutect2, varscan2
- ATRX | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1418531949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATXN3L | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as rs750682579, COSV101019305; called by muse, mutect2, varscan2
- AUTS2 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1353332565; called by muse, mutect2, varscan2
- B3GALT1 | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV59908554; called by muse, mutect2, varscan2
- BCO1 | c.576del p.K193Rfs*5 | Frame Shift Del (DEL) | VAF 61/175 reads (35%) | catalogued as COSV50733134; called by mutect2, pindel, varscan2
- BDP1 | c.7813del p.A2605Qfs*30 | Frame Shift Del (DEL) | VAF 58/148 reads (39%) | catalogued as COSV100703068; called by pindel, varscan2
- BMP6 | c.1006+1G>T p.X336_splice | Splice Site (SNP) | VAF 38/58 reads (66%) | catalogued as COSV51664073; called by muse, mutect2
- BRINP1 | c.1284C>A p.C428* | Nonsense Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV56292447, COSV99774759, COSV99775887; called by muse, mutect2, varscan2
- BTF3L4 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV57630446; called by muse, mutect2, varscan2
- C16orf91 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as rs199709082, COSV59949975; called by muse, mutect2, varscan2
- C1orf53 | c.326A>G p.H109R | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs772544322; called by muse, mutect2, varscan2
- C8orf88 | c.73+1G>T p.X25_splice | Splice Site (SNP) | VAF 37/82 reads (45%) | catalogued as COSV72865525; called by muse, mutect2, varscan2
- CACNA1F | c.3544C>T p.R1182C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782492780, COSV59902917; called by muse, mutect2, varscan2
- CACNG8 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as COSV54414766; called by muse, mutect2
- CALCRL | c.1235A>T p.N412I | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs922393729; called by muse, mutect2, varscan2
- CAMK1G | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); catalogued as COSV50522878; called by muse, mutect2, varscan2
- CAMK2A | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV62247600; called by muse, mutect2, varscan2
- CBARP | c.684C>G p.F228L (on ENST00000382477; = p.F208L on NM_152769.3) | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1465245819; called by muse, mutect2, varscan2
- CBLIF | c.1149G>C p.K383N | Missense Mutation (SNP) | VAF 100/312 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs777288222; called by muse, varscan2
- CBLIF | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV57238937; called by muse, mutect2, varscan2
- CBLN4 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as rs746116052; called by muse, mutect2, varscan2
- CCDC136 | c.1388C>A p.T463K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV52801795; called by muse, mutect2, varscan2
- CCDC168 | c.15279C>A p.N5093K | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT tolerated (0.31); PolyPhen benign (0.232); catalogued as rs780757170; called by muse, mutect2, varscan2
- CCDC93 | c.363G>A p.Q121= | Splice Region (SNP) | VAF 16/78 reads (21%) | catalogued as COSV60121186; called by muse, varscan2
- CCM2L | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1471615975; called by muse, mutect2, varscan2
- CDC42BPA | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs200713147; called by muse, mutect2
- CDH9 | c.141G>C p.M47I | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50279664, COSV99144018; called by muse, mutect2, varscan2
- CEP83 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as COSV100352617; called by muse, mutect2, varscan2
- CFAP47 | c.4163C>G p.S1388C | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as rs1018451295; called by muse, mutect2, varscan2
- CFAP69 | c.1527G>T p.Q509H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs368130517; called by muse, mutect2, varscan2
- CFHR2 | c.497C>A p.S166* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | catalogued as COSV100804416; called by muse, mutect2, varscan2
- CHEK2 | c.653T>C p.V218A (on ENST00000382580 / NM_001005735.2; = p.V175A on NM_007194.4) | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs1555926862, COSV60419438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHL1 | c.3509G>A p.G1170E (on ENST00000397491 / NM_001253387.1; = p.G1186E on NM_006614.4) | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.958); catalogued as rs1395500082; called by muse, mutect2, varscan2
- CHRM2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV57769053; called by muse, mutect2, varscan2
- CLCNKA | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 117/233 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777748952; called by muse, mutect2, varscan2
- CLEC6A | c.553A>T p.T185S | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101165602; called by muse, mutect2, varscan2
- CLRN2 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72512568; called by muse, mutect2, varscan2
- CNPY4 | c.249_250del p.X83_splice | Splice Site (DEL) | VAF 27/131 reads (21%) | catalogued as rs751666560; called by pindel, varscan2
- COL19A1 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV59584486; called by muse, mutect2, varscan2
- COL25A1 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67649797; called by muse, mutect2, varscan2
- COL3A1 | c.1348-1G>C p.X450_splice | Splice Site (SNP) | VAF 25/184 reads (14%) | catalogued as rs112292671; called by muse, mutect2, varscan2
- COL6A6 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62025448; called by muse, mutect2, varscan2
- COL6A6 | c.5734-1G>C p.X1912_splice | Splice Site (SNP) | VAF 32/102 reads (31%) | catalogued as COSV62023219; called by muse, varscan2
- COLGALT2 | c.762C>A p.Y254* | Nonsense Mutation (SNP) | VAF 43/95 reads (45%) | catalogued as COSV62299396; called by muse, mutect2, varscan2
- COPG2 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.247); catalogued as rs531388882, COSV100449648, COSV58407235; called by muse, mutect2, varscan2
- CPE | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV68579766; called by muse, mutect2, varscan2
- CRB1 | c.2291G>T p.R764L | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs375040930, CM130791; called by muse, mutect2, varscan2
- CRYBG1 | c.4640C>A p.S1547Y | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV64812149; called by muse, mutect2, varscan2
- CRYBG3 | c.6139G>C p.D2047H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246360124; called by muse, mutect2, varscan2
- CSF2RA | c.1187T>A p.V396E | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100818049; called by muse, mutect2, varscan2
- CSMD1 | c.10343G>T p.G3448V (on ENST00000520002; = p.G3447V on NM_033225.6) | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100151449; called by muse, mutect2, varscan2
- CSMD3 | c.7957C>T p.R2653* (on ENST00000297405 / NM_001363185.1; = p.R2549* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as rs1443055427, COSV52140719, COSV52280497; called by muse, varscan2
- CSMD3 | c.1459C>A p.P487T (on ENST00000297405 / NM_001363185.1; = p.P383T on NM_052900.3) | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99822903; called by muse, mutect2, varscan2
- CSPG4 | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1387915856, COSV57892314; called by muse, mutect2, varscan2
- CTNNA2 | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as rs1258444394, COSV100561543, COSV58151794; called by muse, mutect2, varscan2
- CUBN | c.6913C>T p.Q2305* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | catalogued as COSV64706834; called by muse, mutect2, varscan2
- CUL3 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as COSV52369154; called by muse, mutect2, varscan2
- CXorf56 | c.564+1G>T p.X188_splice (on ENST00000536133 / NM_001170570.2; = p.X202_splice on NM_022101.4) | Splice Site (SNP) | VAF 27/135 reads (20%) | catalogued as COSV100233532, COSV57438500; called by muse, mutect2, varscan2
- CYTIP | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as rs762663690, COSV51633401; called by muse, mutect2, varscan2
- DCAF12L1 | c.810C>A p.C270* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100948495; called by muse, mutect2, varscan2
- DCAF8L1 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV71595538; called by muse, mutect2, varscan2
- DCAF8L1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.114); catalogued as COSV71595420, COSV71595480; called by muse, varscan2
- DCPS | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs201108066; called by muse, mutect2, varscan2
- DES | c.1412A>T p.*471Lext*151 | Nonstop Mutation (SNP) | VAF 53/292 reads (18%) | catalogued as COSV100900394; called by muse, mutect2, varscan2
- DGCR8 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV61227294; called by muse, mutect2, varscan2
- DGKK | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); catalogued as rs781899207; called by muse, mutect2, varscan2
- DHX34 | c.1421G>T p.R474L | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60899424; called by muse, mutect2, varscan2
- DLC1 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV52305418; called by muse, mutect2, varscan2
- DMBX1 | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV63602521; called by muse, mutect2, varscan2
- DMD | c.1649G>C p.R550P | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1424295439, COSV55869656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMGDH | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs1186669094; called by muse, mutect2, varscan2
- DNAH2 | c.11645G>A p.R3882Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs377446526; called by muse, mutect2
- DNAH5 | c.5005G>A p.A1669T | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294687964, COSV99453100; called by muse, mutect2, varscan2
- DNAH5 | c.4714C>T p.L1572F | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs769020798; called by muse, mutect2, varscan2
- DNAJA4 | c.1159G>C p.G387R (on ENST00000343789; = p.G416R on NM_018602.3) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs757860929; called by muse, mutect2, varscan2
- DNASE1L3 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs777073900, COSV59155704; called by muse, mutect2, varscan2
- DOCK11 | c.1035+2T>A p.X345_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | catalogued as COSV52240209; called by muse, mutect2, varscan2
- DPP10 | c.2310C>A p.Y770* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV59702700; called by muse, mutect2, varscan2
- DPP8 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 43/207 reads (21%) | catalogued as COSV55681395; called by muse, mutect2, varscan2
- DRICH1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as rs1309557807, COSV58503775; called by muse, mutect2, varscan2
- DUOX2 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs138970496; called by muse, mutect2, varscan2
- DVL1 | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 94/169 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs376762325, COSV100229677; called by muse, mutect2, varscan2
- EBF1 | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs759953915, COSV58170878; called by muse, mutect2, varscan2
- EBF3 | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100799158; called by muse, mutect2, varscan2
- EEA1 | c.1482G>T p.Q494H | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59282361; called by muse, mutect2, varscan2
- EIF2AK3 | c.1802G>T p.R601L | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs367551388; called by muse, mutect2, varscan2
- EIF3B | c.2391G>C p.E797D | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1479744250; called by muse, mutect2, varscan2
- EMB | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV57485434; called by muse, mutect2, varscan2
- EN1 | c.1151C>G p.T384R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV54630275, COSV99727023; called by mutect2, varscan2
- EPB42 | c.136C>G p.R46G (on ENST00000441366 / NM_001114134.2; = p.R76G on NM_000119.3) | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.265); catalogued as rs139202348; called by muse, mutect2, varscan2
- ERBB4 | c.1916C>T p.T639M | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs532377012, COSV53542123; called by muse, mutect2, varscan2
- ERN2 | c.775C>A p.R259S | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV99892147; called by muse, mutect2, varscan2
- ERVFRD-1 | c.1591C>A p.R531S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.111); catalogued as COSV65369215; called by muse, mutect2, varscan2
- ESCO1 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 100/194 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs764637494, COSV99331844; called by muse, mutect2, varscan2
- ESR1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV52790518; called by muse, mutect2, varscan2
- ESR1 | c.905A>T p.K302M | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV52781317, COSV99238444; called by muse, mutect2, varscan2
- ESRP2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758778671, COSV52172915; called by muse, mutect2, varscan2
- EYS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 51/150 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV60997179; called by muse, mutect2, varscan2
- F8 | c.6058C>A p.L2020I | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.58); catalogued as COSV64276444; called by muse, mutect2, varscan2
- FAHD2A | c.7G>T p.V3L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1334483091, COSV51977599; called by muse, mutect2, varscan2
- FAM135B | c.1436G>T p.C479F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.154); catalogued as rs750100451; called by muse, mutect2, varscan2
- FAM155B | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52936615; called by muse, varscan2
- FAM71B | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57227834; called by muse, mutect2, varscan2
- FAT3 | c.9827G>T p.R3276L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV53073819; called by muse, mutect2, varscan2
- FBXO38 | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.017); catalogued as rs1368254315; called by muse, mutect2, varscan2
- FLG | c.9217G>C p.E3073Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.334); catalogued as rs778448821; called by mutect2, varscan2
- FLRT2 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58137166; called by muse, mutect2, varscan2
- FN3KRP | c.110G>C p.R37P | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs763449059; called by muse, mutect2, varscan2
- FREM2 | c.4823G>A p.G1608D | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767651775, COSV54844884, COSV54845108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMPD4 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66220665; called by muse, mutect2, varscan2
- FSHR | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs981802105; called by muse, mutect2, varscan2
- FSHR | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100436435; called by muse, varscan2
- FSIP2 | c.20404G>A p.E6802K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58099765; called by muse, mutect2
- FZD9 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.23); catalogued as rs1170781570, COSV60670318; called by muse, mutect2, varscan2
- GABRA3 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV64803758; called by muse, mutect2
- GAS2L3 | c.1835del p.P612Hfs*5 | Frame Shift Del (DEL) | VAF 21/139 reads (15%) | catalogued as rs779549304; called by mutect2, pindel, varscan2
- GBP7 | c.534G>T p.W178C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147357899; called by muse, mutect2, varscan2
- GC | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV56739046; called by muse, varscan2
- GDAP1 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55187007; called by muse, mutect2, varscan2
- GDF6 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs527612795, COSV54626315; called by muse, mutect2, varscan2
- GDPD4 | c.1319C>G p.S440C | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV60017733; called by muse, mutect2, varscan2
- GGA1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746824920, COSV57331546; called by muse, mutect2, varscan2
- GLB1L3 | c.844C>A p.Q282K | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101110968; called by muse, mutect2, varscan2
- GNB3 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as rs367934996; called by muse, mutect2, varscan2
- GPAA1 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 60/144 reads (42%) | catalogued as COSV100284173; called by muse, mutect2, varscan2
- GTDC1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1410736632; called by muse, mutect2, varscan2
- GTF3C1 | c.1102A>T p.M368L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV100649049; called by muse, mutect2
- GZMA | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1387974280, COSV99031561; called by muse, mutect2, varscan2
- H3C2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52517721, COSV52518221; called by muse, mutect2, varscan2
- HBE1 | c.440A>T p.H147L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53081598; called by muse, varscan2
- HCN4 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1209174833, COSV56083118; called by muse, mutect2, varscan2
- HDGFL1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100014761, COSV57751483; called by muse, mutect2, varscan2
- HEATR1 | c.789G>C p.M263I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV63983501; called by muse, mutect2, varscan2
- HECW2 | c.4436G>T p.R1479L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs143511416, COSV53659825; called by muse, mutect2, varscan2
- HHATL | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs755764290; called by muse, mutect2, varscan2
- HOXA10 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1388106206; called by muse, mutect2, varscan2
- HOXB1 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53316671, COSV53317264; called by muse, varscan2
- HRC | c.1200G>C p.K400N | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV53255627, COSV53257599; called by muse, mutect2, varscan2
- HS2ST1 | c.143A>T p.H48L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs983091583; called by muse, varscan2
- HTR1B | c.521G>T p.W174L | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64052049; called by muse, mutect2, varscan2
- IAH1 | c.49C>G p.R17G | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV53012503; called by muse, mutect2, varscan2
- IFT140 | c.1688C>G p.A563G | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.436); catalogued as COSV68494845; called by muse, mutect2, varscan2
- IGKV1-5 | c.169T>A p.W57R | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1176715016; called by muse, mutect2, varscan2
- IGKV2-24 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs773063087; called by muse, mutect2, varscan2
- IGLL5 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV101597142; called by muse, mutect2, varscan2
- IGLL5 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as COSV66537783; called by muse, mutect2, varscan2
- IKZF2 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59581320; called by muse, mutect2, varscan2
- IL27 | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV60493060; called by muse, mutect2, varscan2
- IL2RA | c.433G>T p.G145W | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56922330; called by muse, mutect2, varscan2
- IMPACT | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52422362; called by muse, mutect2, varscan2
- IMPG2 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs375330175, COSV51985643; called by muse, mutect2, varscan2
- INTS8 | c.2167C>G p.Q723E | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.554); catalogued as rs1426860598; called by muse, mutect2, varscan2
- IRS4 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs1314390113; called by muse, mutect2, varscan2
- ITGA11 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59879813; called by muse, mutect2, varscan2
- ITGA5 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104394745; called by muse, mutect2, varscan2
- ITGAX | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1349872317, COSV51641530; called by muse, mutect2, varscan2
- ITGB4 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.73); catalogued as COSV99564512; called by muse, mutect2, varscan2
- ITIH5 | c.2312T>G p.L771R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs551710682; called by muse, mutect2, varscan2
- ITPR1 | c.6757G>T p.E2253* (on ENST00000354582; = p.E2198* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV56978074; called by muse, varscan2
- KCNA1 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1288483498; called by muse, mutect2, varscan2
- KCNC1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1349528647; called by muse, mutect2, varscan2
- KCNH7 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59811411; called by muse, mutect2, varscan2
- KCNJ10 | c.1123C>G p.R375G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs751338154, COSV63633400, COSV63634235; called by muse, mutect2, varscan2
- KCNJ4 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1168216725, COSV100340995; called by muse, varscan2
- KCNT2 | c.3086C>T p.S1029F | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV54062837; called by muse, mutect2, varscan2
- KCNT2 | c.2888C>A p.S963Y | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV54093408; called by muse, mutect2, varscan2
- KCNU1 | c.2641G>C p.E881Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV101299393; called by muse, mutect2, varscan2
- KEAP1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV50260447, COSV50260545; called by muse, mutect2, varscan2
- KIAA0232 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.246); catalogued as COSV100300730; called by muse, mutect2, varscan2
- KIF25 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 79/217 reads (36%) | catalogued as COSV63028253; called by muse, mutect2, varscan2
- KIFAP3 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV63030754; called by muse, varscan2
- KLHL1 | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs373280757; called by muse, mutect2, varscan2
- KLHL1 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | catalogued as COSV64767138, COSV64784452; called by muse, mutect2
- KLHL11 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV59861657; called by muse, varscan2
- KMT2C | c.12443C>T p.P4148L | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs141718495; called by muse, mutect2, varscan2
- KPRP | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 48/212 reads (23%) | catalogued as COSV64221984, COSV64222902; called by muse, mutect2, varscan2
- KRT6A | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs768169678, COSV58103717; called by muse, mutect2, varscan2
- KRTAP13-1 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs553954116; called by muse, mutect2, varscan2
- LAMA1 | c.8761C>T p.R2921* | Nonsense Mutation (SNP) | VAF 135/240 reads (56%) | catalogued as rs1480105908, COSV67533527; called by muse, mutect2, varscan2
- LAMA1 | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as rs1451513103, COSV67533010; called by muse, mutect2, varscan2
- LHFPL4 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 114/374 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV55004774; called by muse, varscan2
- LIFR | c.2986G>T p.V996L | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV54685110; called by muse, mutect2, varscan2
- LMBR1 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV62222296; called by muse, mutect2, varscan2
- LMX1A | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs909983869, COSV54218563, COSV99672908; called by muse, mutect2
- LONRF1 | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs957297410; called by muse, mutect2, varscan2
- LRP1B | c.12797C>T p.S4266L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV67186926; called by muse, mutect2
- LRP1B | c.6111G>T p.M2037I | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV67194126; called by muse, mutect2, varscan2
- LRRC74A | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV53612362; called by muse, mutect2, varscan2
- LRTM2 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54564140; called by muse, mutect2, varscan2
- LUZP2 | c.716C>A p.P239Q | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV100419014; called by muse, mutect2, varscan2
- LVRN | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs1319168831; called by muse, mutect2, varscan2
- MACF1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 52/88 reads (59%) | catalogued as rs1220306902; called by muse, mutect2, varscan2
- MAGEB6B | c.596del p.A199Efs*19 | Frame Shift Del (DEL) | VAF 33/124 reads (27%) | catalogued as COSV69689828; called by mutect2, pindel, varscan2
- MAGEC1 | c.2897G>C p.R966T | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs765155185; called by muse, mutect2, varscan2
- MAGED1 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV58514372; called by muse, mutect2, varscan2
- MAGI2 | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs748239451, COSV62643585; called by muse, mutect2
- MAGIX | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100891871, COSV66255661; called by muse, varscan2
- MAP3K15 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV58841640; called by muse, mutect2, varscan2
- MARCHF4 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs767933685; called by muse, mutect2, varscan2
- MCC | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as rs1232658549; called by muse, mutect2, varscan2
- MCF2 | c.1011C>A p.C337* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100645029; called by muse, mutect2, varscan2
- MCUR1 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 63/136 reads (46%) | catalogued as rs1205754132; called by muse, mutect2, varscan2
- MECR | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 112/204 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV55284456; called by muse, mutect2, varscan2
- MFRP | c.275C>A p.P92H (on ENST00000449574; = p.P468H on NM_031433.4) | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV60991293; called by muse, mutect2, varscan2
- MGAM | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1040384722; called by muse, varscan2
- MGAM2 | c.5869G>C p.V1957L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.34); catalogued as rs1362110363; called by muse, mutect2, varscan2
- MIIP | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs964729849; called by muse, mutect2, varscan2
- MMP8 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 92/358 reads (26%) | catalogued as rs1050559466, COSV52631065; called by muse, varscan2
- MOCS3 | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 31/120 reads (26%) | catalogued as COSV54866130, COSV54866265; called by muse, mutect2, varscan2
- MOGAT2 | c.875A>G p.K292R | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs796734658; called by muse, mutect2, varscan2
- MPDZ | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1347566879; called by muse, mutect2, varscan2
- MSLN | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.216); catalogued as rs751744116, COSV53503298; called by muse, mutect2
- MUC12 | c.15928G>A p.E5310K (on ENST00000379442; = p.E5167K on NM_001164462.1) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (1); catalogued as rs556807992, COSV100523586; called by muse, mutect2, varscan2
- MUC16 | c.3382G>T p.A1128S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as COSV67494919; called by muse, mutect2, varscan2
- MUC3A | c.7348T>A p.S2450T | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious, low confidence (0.01); catalogued as COSV100114135; called by muse, mutect2, varscan2
- MUC5AC | c.1468G>C p.V490L | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT tolerated (0.34); catalogued as rs140943417, COSV62254462; called by muse, mutect2, varscan2
- MUC5B | c.9748A>T p.T3250S | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1192647390; called by muse, mutect2, varscan2
- MVB12B | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 41/95 reads (43%) | catalogued as COSV63260296; called by muse, mutect2, varscan2
- MYBPC2 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 113/183 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs373805656, COSV63098550; called by muse, mutect2, varscan2
- MYCN | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV55261659; called by muse, mutect2, varscan2
- MYH2 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV55438753; called by muse, mutect2, varscan2
- MYO15A | c.368G>C p.R123P | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV52760772, COSV52769060; called by muse, mutect2, varscan2
- MYO5C | c.138G>C p.T46= | Splice Region (SNP) | VAF 31/120 reads (26%) | catalogued as rs192901094, COSV99954050; called by muse, mutect2, varscan2
- NADK | c.263+3G>A | Splice Region (SNP) | VAF 31/52 reads (60%) | catalogued as rs778473646; called by muse, mutect2, varscan2
- NETO1 | c.275C>A p.P92Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV55012483; called by muse, mutect2, varscan2
- NEXMIF | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV50021711; called by muse, mutect2, varscan2
- NF1 | c.6515C>T p.S2172L (on ENST00000358273 / NM_001042492.3; = p.S2151L on NM_000267.3) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV62217901; called by muse, mutect2, varscan2
- NHS | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.021); catalogued as rs1284289077; called by muse, mutect2, varscan2
- NKAP | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV101004235, COSV101004293; called by muse, mutect2, varscan2
- NLRC3 | c.1878G>T p.Q626H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs866618470, COSV100072570; called by muse, mutect2, varscan2
- NLRC3 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV57089118; called by muse, mutect2, varscan2
- NPAP1 | c.1207C>G p.Q403E | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61511018; called by muse, mutect2, varscan2
- NRG2 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV56834825; called by muse, mutect2, varscan2
- NRIP1 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV59658530; called by muse, mutect2, varscan2
- NRP2 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55929544; called by muse, mutect2, varscan2
- NTHL1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs1474892742; called by muse, mutect2, varscan2
- NTSR1 | c.474C>A p.N158K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV104423505, COSV65138567; called by muse, mutect2, varscan2
- NUP188 | c.3892G>A p.E1298K | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs201805341, COSV65364929; called by muse, mutect2, varscan2
- OCSTAMP | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV54097501; called by muse, mutect2, varscan2
- OPHN1 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs201453412; called by muse, mutect2, varscan2
- OR10G8 | c.397A>T p.S133C | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV101461833; called by muse, mutect2, varscan2
- OR10W1 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1225180631; called by muse, mutect2, varscan2
- OR13C3 | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66166188; called by muse, mutect2, varscan2
- OR14I1 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV100700492, COSV61200709; called by muse, mutect2, varscan2
- OR1J1 | c.639C>A p.C213* | Nonsense Mutation (SNP) | VAF 60/124 reads (48%) | catalogued as COSV52237534; called by muse, mutect2, varscan2
- OR2A2 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV101286684; called by muse, mutect2, varscan2
- OR2M2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.232); catalogued as COSV62898253; called by muse, mutect2
- OR2M4 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60708476; called by muse, mutect2, varscan2
- OR2T4 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100822426, COSV63545270; called by muse, mutect2, varscan2
- OR2T6 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV63216317; called by muse, mutect2, varscan2
- OR4K2 | c.469A>G p.M157V | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs199949460; called by muse, mutect2, varscan2
- OR51E1 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.986); catalogued as COSV67810176; called by muse, varscan2
- OR5B12 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as COSV56906260; called by muse, mutect2, varscan2
- OR5J2 | c.841G>T p.G281W | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV56623109; called by muse, mutect2, varscan2
- OR5L1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs534141468, COSV61732926; called by muse, mutect2, varscan2
- OR5L2 | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101004259, COSV65723457; called by muse, mutect2, varscan2
- OR5T3 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV57381722; called by muse, mutect2, varscan2
- OR6K2 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV62743504; called by muse, mutect2, varscan2
- OR8D2 | c.412C>A p.H138N | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100658916; called by muse, mutect2, varscan2
- OR8H1 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766483878; called by muse, mutect2, varscan2
- OR9Q1 | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV59046341; called by muse, mutect2, varscan2
- OSBPL6 | c.2222G>C p.R741T | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV51921108; called by muse, varscan2
- OSBPL8 | c.2509A>G p.I837V | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV53881894; called by muse, varscan2
- OTOF | c.3967G>T p.E1323* (on ENST00000272371 / NM_194248.3; = p.E556* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 50/244 reads (20%) | catalogued as COSV55502199; called by muse, varscan2
- P4HA3 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59043845; called by muse, mutect2, varscan2
- PABPC5 | c.279G>T p.W93C | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57039069, COSV57043424; called by muse, mutect2, varscan2
- PANK4 | c.1559del p.P520Rfs*7 | Frame Shift Del (DEL) | VAF 36/92 reads (39%) | catalogued as COSV65867749; called by mutect2, pindel, varscan2
- PASD1 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV64857678; called by muse, mutect2, varscan2
- PCDH15 | c.4631C>A p.T1544K | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.227); catalogued as COSV64679263; called by muse, varscan2
- PCDH15 | c.3186del p.I1063Lfs*29 | Frame Shift Del (DEL) | VAF 98/240 reads (41%) | catalogued as COSV100219086; called by mutect2, pindel, varscan2
- PCDH19 | c.1115G>C p.R372P | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99720061; called by muse, mutect2, varscan2
- PCDHA4 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.434); catalogued as rs1311161177, COSV63541084, COSV99061534; called by muse, mutect2, varscan2
- PCDHA8 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65338768; called by muse, mutect2, varscan2
- PCDHB10 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV53379818; called by muse, mutect2, varscan2
- PCDHB8 | c.1662C>A p.D554E | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV50753765; called by muse, mutect2, varscan2
- PDE1C | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58515097, COSV58527678; called by muse, mutect2, varscan2
- PELP1 | c.3349C>T p.P1117S | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as rs761086600; called by muse, mutect2, varscan2
- PHKA2 | c.136del p.D46Ifs*37 | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | catalogued as CD110407; called by mutect2, pindel, varscan2
- PID1 | c.652G>T p.A218S (on ENST00000354069 / NM_001330156.1; = p.A216S on NM_017933.5) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100819951; called by muse, mutect2, varscan2
- PIK3C2G | c.2614G>T p.E872* (on ENST00000676171; = p.E831* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV56818170; called by muse, mutect2, varscan2
- PIKFYVE | c.5191G>C p.E1731Q | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV52241010; called by muse, mutect2, varscan2
- PIP4K2C | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV100723874; called by muse, mutect2, varscan2
- PKP4 | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61578774; called by muse, mutect2, varscan2
- PLEC | c.1357-1G>T p.X453_splice (on ENST00000322810 / NM_201380.4; = p.X343_splice on NM_000445.5) | Splice Site (SNP) | VAF 32/171 reads (19%) | catalogued as COSV100519689; called by muse, mutect2, varscan2
- PLIN1 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200235164, COSV55584448; called by muse, mutect2, varscan2
- PNLIP | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65041059; called by muse, varscan2
- POF1B | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); catalogued as rs768124779; called by muse, mutect2
- POTEE | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 57/353 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV100387675; called by muse, mutect2, varscan2
- POU3F4 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV64540727; called by muse, varscan2
- POU3F4 | c.442G>T p.G148W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100937180; called by muse, varscan2
- PPP1R9B | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1289500721, COSV57541806; called by muse, mutect2, varscan2
- PRAMEF2 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs776428150, COSV53574151; called by muse, mutect2, varscan2
- PRDM14 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 35/168 reads (21%) | catalogued as COSV99400483; called by muse, mutect2
- PRDM9 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as COSV57013195; called by muse, mutect2, varscan2
- PRKAG3 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52102459; called by muse, mutect2, varscan2
- PRKCB | c.189G>C p.Q63H | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV57770822; called by muse, mutect2, varscan2
- PRPH | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV57678551; called by muse, mutect2, varscan2
- PRSS37 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV63339256; called by muse, mutect2, varscan2
- PRUNE2 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65029841; called by muse, mutect2, varscan2
- PRX | c.3135G>C p.L1045F | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV52531218; called by muse, mutect2, varscan2
- PSG4 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54937194; called by muse, mutect2, varscan2
- PSG8 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 137/265 reads (52%) | catalogued as rs768915559, COSV60613853; called by muse, mutect2, varscan2
- PTPRK | c.2767G>A p.D923N (on ENST00000368215 / NM_001291984.2; = p.D924N on NM_002844.4) | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs902630929, COSV63893699; called by muse, mutect2, varscan2
- PTPRR | c.1524G>C p.K508N | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs752288704; called by muse, mutect2, varscan2
- PTPRS | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53610215; called by muse, mutect2, varscan2
- PTPRZ1 | c.3884del p.T1295Rfs*29 | Frame Shift Del (DEL) | VAF 56/146 reads (38%) | catalogued as COSV66436120; called by mutect2, pindel*, varscan2
- PXDN | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV99413420; called by muse, mutect2, varscan2
- PXDNL | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs749235862; called by muse, mutect2, varscan2
- PYHIN1 | c.880C>A p.P294T | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as COSV63721880; called by muse, mutect2, varscan2
- RAD54B | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100280149; called by muse, mutect2, varscan2
- RASAL3 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs760390003; called by muse, mutect2, varscan2
- RASSF3 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as rs774662298; called by muse, mutect2, varscan2
- RASSF7 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs149920152; called by muse, mutect2, varscan2
- RBM10 | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV61307822; called by muse, mutect2, varscan2
- RELN | c.4814G>A p.G1605E | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267601214, COSV58986960; called by muse, mutect2, varscan2
- RELN | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633869, COSV59036527; called by muse, mutect2, varscan2
- RIPPLY1 | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV52173958, COSV99343655; called by muse, mutect2, varscan2
- RNF128 | c.1022C>T p.P341L (on ENST00000255499 / NM_194463.2; = p.P315L on NM_024539.3) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs749680552; called by muse, mutect2, varscan2
- RNF13 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as rs781271591, COSV53522601; called by muse, mutect2, varscan2
- RNF213 | c.11787C>G p.F3929L | Missense Mutation (SNP) | VAF 113/249 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs780485953; called by muse, mutect2, varscan2
- RPGRIP1L | c.1163A>G p.Q388R | Missense Mutation (SNP) | VAF 79/143 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs181526554; called by muse, mutect2, varscan2
- RPS6KA6 | c.1120G>T p.G374C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs1288271564, COSV53117997; called by muse, mutect2, varscan2
- RPTN | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 85/248 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV60166073; called by muse, mutect2, varscan2
- RUFY4 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs569550024, COSV60247405; called by muse, mutect2, varscan2
- RYR2 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63671041; called by muse, varscan2
- RYR3 | c.6889C>G p.R2297G (on ENST00000389232; = p.R2298G on NM_001036.6) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109571; called by muse, mutect2, varscan2
- RYR3 | c.8700del p.G2901Afs*25 (on ENST00000389232; = p.G2902Afs*25 on NM_001036.6) | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as COSV66778488; called by mutect2, pindel, varscan2
- S100P | c.139-1G>C p.X47_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as rs756556620; called by muse, mutect2
- SACS | c.3697G>T p.D1233Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs1180900696; called by muse, mutect2, varscan2
- SAP30L | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99770355; called by muse, mutect2, varscan2
- SAV1 | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 54/95 reads (57%) | catalogued as rs1422697297; called by muse, mutect2, varscan2
- SCG2 | c.1639A>G p.I547V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs145604492; called by muse, mutect2, varscan2
- SDR16C5 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58126752; called by muse, mutect2, varscan2
- SELENOO | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV50542418, COSV99955959; called by muse, mutect2, varscan2
- SEMA6B | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as rs745664571; called by muse, mutect2, varscan2
- SEMA6B | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1018383732; called by muse, mutect2, varscan2
- SEPTIN3 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as rs369032977, COSV52171025; called by muse, mutect2, varscan2
- SHCBP1L | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763799158; called by muse, mutect2, varscan2
- SHH | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV51918459; called by muse, mutect2, varscan2
- SHOX | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as CM064267, COSV61862539; called by muse, varscan2
- SI | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV100016592; called by muse, mutect2, varscan2
- SIDT1 | c.1453T>G p.C485G | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53500488; called by muse, mutect2, varscan2
- SIPA1L2 | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 110/300 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53390188, COSV99480013; called by muse, mutect2, varscan2
- SIRPB2 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63124136; called by muse, mutect2
- SLC17A6 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs878877170, COSV54134483; called by muse, mutect2, varscan2
- SLC17A8 | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs759180942; called by muse, mutect2, varscan2
- SLC39A11 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1451654486; called by muse, mutect2, varscan2
- SLC52A1 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1182838787; called by muse, mutect2, varscan2
- SLC5A10 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs768462645, COSV100524948; called by muse, mutect2, varscan2
- SLC6A5 | c.2221C>A p.P741T | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV100116925, COSV54233350; called by muse, mutect2, varscan2
- SLC7A5 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV55365387; called by muse, varscan2
- SLC9A8 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV64288808; called by muse, mutect2, varscan2
- SMAD4 | c.394C>G p.H132D | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61683986, COSV61688959, COSV61693892; called by muse, mutect2, varscan2
- SNRNP48 | c.747G>T p.M249I | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.643); catalogued as COSV60940975; called by muse, mutect2, varscan2
- SOX5 | c.1269C>G p.N423K | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV58650645; called by muse, mutect2, varscan2
- SPANXN1 | c.59A>G p.N20S | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV65122845; called by muse, varscan2
- SPTA1 | c.6275T>A p.L2092Q | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63754547; called by muse, mutect2, varscan2
- SPTBN1 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100443145; called by muse, mutect2, varscan2
- SPTBN5 | c.6362G>A p.R2121Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770835859; called by muse, mutect2, varscan2
- SRRM1 | c.905A>G p.H302R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs1033833674; called by muse, mutect2, varscan2
- SRRM3 | c.1951G>T p.G651W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs782363037; called by muse, varscan2
- ST8SIA1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs770322700; called by muse, mutect2, varscan2
- STAB2 | c.906G>A p.Q302= | Splice Region (SNP) | VAF 5/35 reads (14%) | catalogued as rs761613744; called by muse, varscan2
- STK11 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 40/86 reads (47%) | catalogued as COSV58825370; called by muse, mutect2, varscan2
- STK11 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as rs759473833, COSV100480973, COSV58825109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STK32B | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752188160; called by muse, mutect2, varscan2
- STYXL2 | c.2873C>A p.S958Y | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV54811600; called by muse, mutect2, varscan2
- SUCO | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs1156243233, COSV55264835; called by muse, mutect2, varscan2
- SV2B | c.765G>C p.W255C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57702234; called by muse, mutect2, varscan2
- SYNE1 | c.3889G>T p.A1297S (on ENST00000367255 / NM_182961.4; = p.A1304S on NM_033071.3) | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV99549415; called by muse, mutect2, varscan2
- SYT4 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.06); catalogued as COSV54900061; called by muse, mutect2, varscan2
- TAF1L | c.3604G>C p.E1202Q | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99643959; called by muse, mutect2, varscan2
- TAGLN3 | c.381G>T p.R127S | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV56328757; called by muse, mutect2, varscan2
- TBC1D25 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100952109; called by muse, mutect2, varscan2
- TBX22 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV64785585; called by muse, mutect2, varscan2
- TBX5 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1426492228, COSV59858496; called by muse, mutect2, varscan2
- TCHP | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV57166745; called by muse, mutect2, varscan2
- TCTN2 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs757725319; called by muse, mutect2, varscan2
- TENM1 | c.7960G>T p.A2654S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs1398212576, COSV64429335; called by muse, mutect2, varscan2
- TEX101 | c.382G>C p.E128Q (on ENST00000598265 / NM_001130011.3; = p.E146Q on NM_031451.4) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV53663193; called by muse, varscan2
- TEX15 | c.3233C>T p.P1078L (on ENST00000256246; = p.P1461L on NM_001350162.2) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56343427, COSV56356149; called by muse, mutect2, varscan2
- TGFB2 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.089); catalogued as COSV65108629, COSV65110176; called by muse, mutect2, varscan2
- THNSL2 | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886979870; called by muse, mutect2, varscan2
- THSD7B | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55648336, COSV55742726; called by muse, mutect2, varscan2
- TIMD4 | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280735395, COSV50854009; called by muse, mutect2, varscan2
- TMEM135 | c.749G>T p.C250F | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as CM119193; called by muse, mutect2, varscan2
- TMEM144 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99646946; called by muse, mutect2, varscan2
- TMEM196 | c.391T>A p.Y131N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.189); catalogued as rs896813649; called by muse, mutect2, varscan2
- TMEM215 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV61363627; called by muse, mutect2, varscan2
- TMPRSS11A | c.1073G>C p.G358A | Missense Mutation (SNP) | VAF 114/241 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58358573; called by muse, varscan2
- TMPRSS9 | c.1804G>A p.G602R (on ENST00000648592; = p.G568R on NM_182973.2) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs549297570, COSV60227414; called by muse, varscan2
- TMTC1 | c.1093G>T p.A365S (on ENST00000539277 / NM_001193451.2; = p.A257S on NM_175861.3) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as COSV55489737; called by muse, varscan2
- TMTC2 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754292590; called by muse, mutect2, varscan2
- TNFRSF13B | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM077982; called by muse, mutect2, varscan2
- TNFRSF1B | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 40/62 reads (65%) | catalogued as COSV66163595; called by muse, mutect2, varscan2
- TNKS1BP1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs778028760; called by muse, mutect2, varscan2
- TOM1L1 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100779134, COSV61947740; called by muse, mutect2, varscan2
- TRABD2A | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs567498576; called by muse, mutect2, varscan2
- TRAK2 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.16); catalogued as COSV60270521; called by muse, mutect2, varscan2
- TRDN | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/152 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs779415181, COSV62123436; called by muse, mutect2, varscan2
- TRIM35 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1226013472; called by muse, mutect2, varscan2
- TRIM77 | c.98G>C p.R33T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.978); catalogued as COSV68065905, COSV99074716; called by muse, mutect2, varscan2
- TRIML2 | c.1256C>A p.P419Q | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV58714513; called by muse, mutect2, varscan2
- TRMT1L | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs747654577; called by muse, mutect2, varscan2
- TRPS1 | c.2578G>C p.G860R (on ENST00000220888 / NM_001330599.2; = p.G873R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); catalogued as COSV55225531; called by muse, mutect2, varscan2
- TSC2 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as COSV54594044; called by muse, mutect2, varscan2
- TSC2 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1060500970; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TSPAN5 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs193921080, COSV59873743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.31561C>A p.P10521T (on ENST00000591111; = p.P9594T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/130 reads (36%) | PolyPhen benign (0.005); catalogued as COSV100616383, COSV60405654; called by muse, mutect2, varscan2
- TUT7 | c.281A>T p.H94L | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.979); catalogued as rs749325538; called by muse, mutect2, varscan2
- UFL1 | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV100990029; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3691C>T p.R1231W | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs767522996; called by muse, mutect2, varscan2
- UPK3B | c.899C>T p.P300L (on ENST00000257632; = p.P272S on NM_001347684.2) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs143366109; called by muse, mutect2, varscan2
- USH2A | c.14504C>A p.P4835Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751908453; called by muse, mutect2, varscan2
- USH2A | c.8283G>T p.M2761I | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV56451233; called by muse, varscan2
- USP36 | c.1174G>T p.G392* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as COSV61751079; called by muse, mutect2, varscan2
- VAV3 | c.1942G>T p.G648* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as rs1029062171; called by muse, mutect2, varscan2
- VILL | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs770448156; called by muse, mutect2, varscan2
- VOPP1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV53390438; called by muse, varscan2
- VPS13B | c.4843C>T p.L1615F | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371397733; called by muse, varscan2
- VPS33B | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs1229006812; called by muse, mutect2, varscan2
- VWA5B2 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99890908; called by muse, mutect2, varscan2
- WDR53 | c.61del p.E21Kfs*23 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as COSV60284895; called by mutect2, pindel, varscan2
- WDR97 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as rs1239809245; called by muse, mutect2, varscan2
- XIRP2 | c.2566G>T p.E856* (on ENST00000628543; = p.E1031* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | catalogued as COSV54720071; called by muse, mutect2, varscan2
- ZC2HC1A | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1241182299, COSV55668102; called by muse, varscan2
- ZC3H13 | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.76); catalogued as COSV54451660; called by muse, mutect2, varscan2
- ZC3H18 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1021180429; called by muse, mutect2, varscan2
- ZC3H7B | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100687026; called by muse, mutect2, varscan2
- ZFHX4 | c.3505G>T p.D1169Y | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51440188; called by muse, varscan2
- ZFHX4 | c.9010G>A p.G3004S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1050279122; called by muse, mutect2, varscan2
- ZHX2 | c.202del p.E68Kfs*23 | Frame Shift Del (DEL) | VAF 17/122 reads (14%) | catalogued as COSV100074080; called by mutect2, pindel, varscan2
- ZMYM3 | c.4049G>T p.R1350L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58735873; called by muse, mutect2, varscan2
- ZNF133 | c.1130C>T p.S377F (on ENST00000316358 / NM_001352454.2; = p.S376F on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60366459; called by muse, mutect2, varscan2
- ZNF208 | c.1228T>A p.S410T | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.536); catalogued as COSV68099887; called by muse, mutect2, varscan2
- ZNF257 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV101448187, COSV71307216; called by muse, mutect2, varscan2
- ZNF280A | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 58/214 reads (27%) | catalogued as rs571241614; called by muse, mutect2, varscan2
- ZNF347 | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967421855; called by muse, mutect2, varscan2
- ZNF423 | c.68C>A p.S23* (on ENST00000563137 / NM_001379286.1; = p.S15* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as rs377503772; called by muse, mutect2, varscan2
- ZNF449 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs781985440; called by muse, mutect2, varscan2
- ZNF626 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 31/55 reads (56%) | catalogued as rs376276756, COSV52482558; called by muse, mutect2, varscan2
- ZNF646 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs550746747; called by muse, mutect2, varscan2
- ZNF804A | c.2300G>T p.R767I | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs765025112, COSV56448920, COSV56469679; called by muse, mutect2, varscan2
- ZP4 | c.1410C>G p.N470K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs536140661, COSV100850661; called by muse, mutect2, varscan2
- ZPLD1 | c.487G>C p.V163L (on ENST00000466937 / NM_001329788.1; = p.V179L on NM_175056.2) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV60356560; called by muse, mutect2, varscan2
- ZSWIM2 | c.1576A>T p.T526S | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV54575220; called by muse, mutect2, varscan2
- ABCB5 | c.3212A>C p.Q1071P (on ENST00000404938 / NM_001163941.2; = p.Q626P on NM_178559.6) | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ABCC11 | c.1792T>C p.Y598H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABHD6 | c.919T>A p.S307T | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.018); called by muse, mutect2
- ACAA1 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACMSD | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ACOT12 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ACSL6 | c.164G>T p.C55F (on ENST00000379240; = p.C80F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ADAM12 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM19 | c.1170G>T p.R390S | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ADAM30 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS17 | c.2016G>T p.Q672H | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADAMTS9 | c.4025G>C p.S1342T | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ADCY10 | c.182C>G p.A61G | Missense Mutation (SNP) | VAF 74/138 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ADGRB3 | c.2853C>A p.F951L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRG4 | c.5339C>A p.P1780H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); called by muse, varscan2
- ADGRL4 | c.22+3G>A | Splice Region (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- ADGRV1 | c.11833G>C p.A3945P | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AFF2 | c.3437C>A p.P1146H | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.111); called by muse, varscan2
- AGBL2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, varscan2
- AGBL3 | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- AGMO | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- AGPS | c.1808G>C p.R603T | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK | c.15172C>T p.P5058S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK | c.11326G>C p.G3776R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- AIG1 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AJM1 | c.1447G>T p.V483L | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP1 | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- AKIRIN1 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH3A2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALKBH7 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- AMELX | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANAPC1 | c.4317C>G p.I1439M | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ANAPC1 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ANHX | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANHX | c.773G>T p.W258L | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD13B | c.1830G>T p.Q610H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ANKRD34A | c.1253C>A p.S418* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- ANKRD36 | c.4308-1G>A p.X1436_splice | Splice Site (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2, varscan2
- ANKRD44 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ANO3 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- APAF1 | c.664G>A p.E222K (on ENST00000551964 / NM_181861.2; = p.E211K on NM_001160.3) | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- APBA2 | c.412G>C p.V138L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- APBA2 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- APEX2 | c.1182G>C p.K394N | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APOA2 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- APOB | c.9049T>A p.F3017I | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.1663G>T p.G555* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- APPL2 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF2 | c.4498G>C p.E1500Q | Missense Mutation (SNP) | VAF 68/346 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARFGEF3 | c.5231A>T p.E1744V | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ARHGAP32 | c.5100C>G p.S1700R (on ENST00000310343 / NM_001378025.1; = p.S1351R on NM_014715.4) | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGAP32 | c.776C>G p.P259R | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- ARHGAP36 | c.1465C>A p.Q489K | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ARHGAP42 | c.1434C>G p.I478M | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ARHGAP6 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ARHGEF40 | c.3547C>G p.L1183V | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ARHGEF40 | c.3692C>T p.S1231F | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ARL13A | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ARX | c.1558C>A p.P520T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ARX | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ASL | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ASTL | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); called by muse, varscan2
- ATG4C | c.1111A>T p.K371* | Nonsense Mutation (SNP) | VAF 95/203 reads (47%) | called by muse, mutect2, varscan2
- ATP10B | c.2900A>G p.Q967R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP11C | c.1582C>A p.Q528K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ATP1A3 | c.2227G>A p.D743N (on ENST00000545399 / NM_001256214.2; = p.D730N on NM_152296.5) | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP2B2 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ATRX | c.134-1G>C p.X45_splice | Splice Site (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- BANK1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- BBOX1 | c.87C>A p.Y29* | Nonsense Mutation (SNP) | VAF 55/134 reads (41%) | called by muse, mutect2, varscan2
- BCAS3 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BCORL1 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.907); called by muse, varscan2
- BCORL1 | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | called by mutect2, varscan2
- BEND3 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- BEX1 | c.130T>A p.C44S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BLOC1S4 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- BLOC1S4 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- BPNT2 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BRINP1 | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRINP2 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, varscan2
- BRWD3 | c.4934T>A p.F1645Y | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C10orf90 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- C11orf87 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- C17orf97 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1S | c.1319G>C p.G440A | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C1orf185 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- C1orf35 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- C20orf96 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- C2CD3 | c.6199G>A p.D2067N | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C3orf56 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C6 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 51/218 reads (23%) | called by muse, mutect2, varscan2
- C6orf118 | c.74G>C p.C25S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.114); called by muse, mutect2
- C7 | c.2132C>G p.S711* | Nonsense Mutation (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2, varscan2
- CA6 | c.64G>C p.D22H | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CA6 | c.80-1G>A p.X27_splice | Splice Site (SNP) | VAF 10/14 reads (71%) | called by muse, varscan2
- CABCOCO1 | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNA1E | c.6696C>A p.Y2232* (on ENST00000367573 / NM_001205293.3; = p.Y2189* on NM_000721.4) | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.2849G>C p.W950S | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CADPS | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAMK1G | c.869C>G p.S290* | Nonsense Mutation (SNP) | VAF 58/174 reads (33%) | called by muse, mutect2, varscan2
- CAPN6 | c.382T>A p.F128I | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CARD11 | c.2899C>A p.R967S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARD17 | c.*1del | Splice Site (DEL) | VAF 36/122 reads (30%) | called by mutect2, pindel, varscan2
- CATSPERD | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CATSPERD | c.1506+1G>T p.X502_splice | Splice Site (SNP) | VAF 35/70 reads (50%) | called by muse, mutect2, varscan2
- CBY1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CBY2 | c.1105C>A p.L369M | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC14 | c.1700C>T p.S567F (on ENST00000488653; = p.S519F on NM_022757.5) | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CCDC144A | c.3991G>C p.E1331Q | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, varscan2
- CCDC22 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CCDC73 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- CCDC78 | c.890_897del p.R297Pfs*12 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- CCDC78 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC88B | c.2005G>T p.G669C | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CCL17 | c.214A>T p.I72F | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CCL18 | c.17C>G p.A6G | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CCM2L | c.1280G>T p.G427V (on ENST00000452892 / NM_001365692.1; = p.G406C on NM_080625.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CCN5 | c.183_184insT p.E62* | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, varscan2
- CD19 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- CD6 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CD84 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CDC42 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH11 | c.2057G>T p.G686V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH22 | c.1838C>A p.T613N | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CDH23 | c.4412C>T p.T1471I | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDHR4 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDHR4 | c.896C>A p.S299* | Nonsense Mutation (SNP) | VAF 51/156 reads (33%) | called by muse, mutect2, varscan2
- CDKN2AIP | c.1450C>G p.P484A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CDON | c.1198+1del p.X400_splice | Splice Site (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- CDX2 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CENPI | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, varscan2
- CEP152 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP164 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CEP170 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP46 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.097); called by muse, mutect2
- CHD9 | c.5942G>A p.R1981Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHL1 | c.3410G>T p.S1137I (on ENST00000397491 / NM_001253387.1; = p.S1153I on NM_006614.4) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CHPF2 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CHRM4 | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA1 | c.838C>A p.L280M (on ENST00000261007 / NM_001039523.3; = p.L255M on NM_000079.4) | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHRNA9 | c.698T>A p.L233Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA9 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRNB3 | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CIP2A | c.2622G>T p.Q874H | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLASP1 | c.3989A>G p.K1330R | Missense Mutation (SNP) | VAF 70/317 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLDN19 | c.252G>C p.M84I | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN5 | c.334C>T p.P112S (on ENST00000618236 / NM_001363066.2; = p.P197S on NM_003277.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLGN | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, varscan2
- CNOT4 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CNTN6 | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CNTNAP2 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CNTNAP3 | c.3865T>A p.*1289Kext*6 | Nonstop Mutation (SNP) | VAF 86/637 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.2182G>T p.G728W | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTNAP3 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- COG1 | c.2865A>T p.R955S | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- COG8 | c.1406T>A p.L469H | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL12A1 | c.4229A>T p.D1410V | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- COL12A1 | c.3770G>C p.R1257T | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL17A1 | c.1693C>G p.L565V | Missense Mutation (SNP) | VAF 129/254 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- COL4A1 | c.1519G>T p.G507C | Missense Mutation (SNP) | VAF 195/383 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A5 | c.2273C>A p.P758Q | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- COL4A5 | c.3068C>A p.P1023H | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- COL6A5 | c.5229A>C p.E1743D | Missense Mutation (SNP) | VAF 98/310 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- COL6A6 | c.3997C>A p.L1333M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- COL6A6 | c.5024C>A p.P1675H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- COL9A3 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORO1A | c.1228C>A p.L410M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CPLANE2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CPLX4 | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CPNE9 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CR2 | c.2758G>A p.G920R | Missense Mutation (SNP) | VAF 53/276 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRELD1 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CROCC | c.2058G>T p.R686S | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CRYGB | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CSE1L | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNA2 | c.657G>C p.M219I | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTNND2 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.8879T>A p.L2960* | Nonsense Mutation (SNP) | VAF 72/159 reads (45%) | called by muse, mutect2, varscan2
- CUL9 | c.4341C>T p.F1447= | Splice Region (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- CXorf66 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, varscan2
- CYFIP1 | c.715del p.A239Qfs*4 | Frame Shift Del (DEL) | VAF 59/299 reads (20%) | called by mutect2, pindel, varscan2
- CYP20A1 | c.467A>T p.Y156F | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, varscan2
- DAG1 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- DCAF11 | c.1193A>T p.Q398L | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF8L2 | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- DCDC2C | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 41/99 reads (41%) | called by muse, mutect2, varscan2
- DCHS1 | c.5213G>T p.R1738L | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- DDC | c.332G>T p.C111F | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DDO | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX24 | c.984G>C p.Q328H | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DEFB118 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, varscan2
- DEFB131A | c.209G>A p.W70* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- DHX29 | c.2154G>C p.L718F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DIO2 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 86/164 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DLG2 | c.1503A>T p.Q501H | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- DLG2 | c.1005del p.V336Lfs*16 | Frame Shift Del (DEL) | VAF 55/165 reads (33%) | called by mutect2, pindel, varscan2
- DLX2 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- DMGDH | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, varscan2
- DNAH10 | c.9111G>T p.G3037= (on ENST00000409039; = p.G2976= on NM_207437.3) | Splice Region (SNP) | VAF 69/138 reads (50%) | called by muse, mutect2, varscan2
- DNAH10 | c.9813del p.N3273Tfs*6 (on ENST00000409039; = p.N3212Tfs*6 on NM_207437.3) | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- DNAH6 | c.2843A>G p.Y948C | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DNAH7 | c.3805C>G p.Q1269E | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- DNAJC25-GNG10 | c.443G>C p.R148T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DNER | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- DNM2 | c.2350G>T p.V784L (on ENST00000355667 / NM_001005360.3; = p.V780L on NM_004945.3) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- DOCK7 | c.4274C>T p.S1425F (on ENST00000635253 / NM_001367561.1; = p.S1394F on NM_033407.3) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOT1L | c.82-1G>T p.X28_splice | Splice Site (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- DPP4 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, varscan2
- DPP6 | c.2246-1G>T p.X749_splice (on ENST00000377770 / NM_001364500.2; = p.X687_splice on NM_001936.5) | Splice Site (SNP) | VAF 35/190 reads (18%) | called by muse, mutect2, varscan2
- DRC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/83 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- DSG1 | c.401del p.G134Afs*4 | Frame Shift Del (DEL) | VAF 40/179 reads (22%) | called by mutect2, pindel, varscan2
- DUSP8 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by mutect2, varscan2
- DYNAP | c.67G>T p.G23C (on ENST00000321600; = p.G26C on NM_001307955.1) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- E2F7 | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- EDIL3 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- EFCAB9 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFHB | c.1008G>T p.L336F | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EIF2AK3 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, varscan2
- EIF2AK4 | c.2068A>G p.T690A | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF5B | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- EIPR1 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 49/171 reads (29%) | called by muse, mutect2, varscan2
- ELFN2 | c.1988A>T p.Y663F | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ELK1 | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- EMD | c.82+2T>C p.X28_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | called by muse, varscan2
- EML1 | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 103/183 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPB41L4B | c.2691G>A p.M897I | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- EPHA2 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2
- EPHA6 | c.1379G>T p.S460I | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- EPS8 | c.2021G>C p.R674T | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ERAS | c.620C>G p.A207G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ERBB4 | c.3905G>A p.R1302K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ERCC6L | c.17G>T p.R6M | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ERO1A | c.31del p.L11Sfs*69 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- ERV3-1 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERVMER34-1 | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- ESF1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETNPPL | c.610G>T p.G204* | Nonsense Mutation (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- EVC2 | c.1395G>C p.K465N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- EVX2 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EVX2 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- EXO1 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAIM2 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FAM120C | c.2716G>C p.A906P | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM122A | c.177G>T p.R59S | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM160A2 | c.949C>A p.L317M | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- FAM184B | c.1736C>G p.P579R | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FAM47B | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCB | c.1060del p.L354* | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- FANCD2 | c.3091C>T p.H1031Y | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAT3 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXL13 | c.217+1G>T p.X73_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- FBXL14 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2
- FBXO40 | c.2095T>A p.F699I | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- FBXO8 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXW7 | c.1198G>A p.D400N (on ENST00000281708 / NM_001349798.2; = p.D320N on NM_018315.5) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FER1L6 | c.2529C>G p.S843R | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- FER1L6 | c.3155C>A p.P1052H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FERMT3 | c.1260C>G p.F420L (on ENST00000279227 / NM_178443.3; = p.F416L on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FGD1 | c.1969dup p.T657Nfs*18 | Frame Shift Ins (INS) | VAF 38/295 reads (13%) | called by pindel, varscan2
- FGF13 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF18 | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGF4 | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FHL2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
1,356 further variants in this file (685 protein-altering or splice-affecting, 412 silent, 259 other) are not listed here.
